TCGA case TCGA-EP-A2KA — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/440375d7-cdcd-418a-8992-0a8ca42d290d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 52 years; Vital status: Dead; Days to death: 627 days (1.7 years).

Diagnoses (3)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 52.6 years (19,214 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 627 days (1.7 years); Ishak fibrosis score: 1,2 - Portal Fibrosis.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sorafenib; Days to treatment start: 312 days; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Lung, NOS. Age at diagnosis: 53.4 years (19,507 days); Days to diagnosis: 293 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
3. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Brain, NOS. Age at diagnosis: 53.8 years (19,647 days); Days to diagnosis: 433 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 433 days (1.2 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Pharmaceutical Therapy, NOS, for recurrent disease.

Follow-up (6 entries)
- Day 293 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to recurrence: 293 days.
- Days to follow up: 357 days; Disease response: With Tumor.
- Day 433 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Brain, NOS; Days to recurrence: 433 days (1.2 years).
- Days to follow up: 627 days (1.7 years); Disease response: With Tumor.
- ECOG performance status: 0.
- Follow-up contact recording only the day: day 111.

Molecular and laboratory tests
- Alpha Fetoprotein 13 ng/mL [Blood test normal range lower: 0].
- Platelets 435 (unit not recorded by GDC) [Blood test normal range lower: 140; Blood test normal range upper: 415].
- Creatinine 0.7 mg/dL [Blood test normal range upper: 1].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Height: 178 cm.

Family history
- Relatives with cancer history count: 2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EP-A2KA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 400 mg.
  Slide TCGA-EP-A2KA-01A-01-TSA: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 92; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EP-A2KA-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EP-A2KA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Lobectomy.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Follow-up form 1: Tumor status: With tumor.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 627 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 627 days; disease-free interval: event (new tumor event after initially disease-free), 293 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 293 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EP-A2KA-01A-11D-A182-01): tumor purity 0.62, ploidy 2.34, whole-genome doublings 0.
